Somatic mutation profile of tumor specimen TCGA-06-0749-01A (aliquot TCGA-06-0749-01A-01W-0348-08) from TCGA case TCGA-06-0749, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.8 years (18,571 days).
Specimen TCGA-06-0749-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64d56f67-a022-4e5d-8cfb-19b7cdd7b4dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0749-10A (Blood Derived Normal), aliquot TCGA-06-0749-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd467ad2-3e0e-4ba6-8f52-dccd210ef0f2

The open-access MAF lists 86 somatic variants for this specimen: 70 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 45, Frame Shift Ins 17, Silent 16, Nonsense Mutation 5, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 14/84 reads (17%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- DYSF | c.4200dup p.I1401Hfs*8 | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | catalogued as rs398123786; ClinVar: pathogenic; called by mutect2, varscan2
- EGFR | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 128/288 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs769696078, COSV51770322, COSV99297135; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 30/242 reads (12%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 44/291 reads (15%) | catalogued as rs767549806; called by mutect2, varscan2
- ADCY5 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs1324655717, COSV59193487, COSV59200545; called by muse, mutect2, varscan2
- AGPAT4 | c.907dup p.R303Pfs*60 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | catalogued as rs750826126; called by mutect2, varscan2
- AK7 | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 114/437 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV50874149; called by muse, mutect2, varscan2
- ANKFN1 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs777136761, COSV59451736; called by muse, mutect2, varscan2
- ATRX | c.5240C>G p.T1747R | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64877123, COSV64884721; called by muse, mutect2
- BIRC6 | c.6468T>A p.H2156Q | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV70202019; called by muse, mutect2, varscan2
- BNC2 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs143124811; called by muse, mutect2, varscan2
- CCDC146 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 54/375 reads (14%) | catalogued as rs371350411; called by muse, mutect2, varscan2
- CLCN1 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs753106925, COSV58371407, COSV58373618; called by muse, mutect2, varscan2
- CREBBP | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 80/301 reads (27%) | catalogued as COSV52129560; called by muse, mutect2, varscan2
- CYP4F2 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs550261161, COSV55619400, COSV99685655; called by muse, mutect2
- DAG1 | c.895A>G p.I299V | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.078); catalogued as COSV58185337; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 10/85 reads (12%) | catalogued as rs756407271; called by mutect2, varscan2
- FAM91A1 | c.1253A>C p.D418A | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201587994; called by mutect2, varscan2
- FUT8 | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 276/819 reads (34%) | catalogued as COSV61287028; called by muse, mutect2, varscan2
- GAL | c.250A>G p.N84D | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV55764304; called by mutect2, varscan2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | catalogued as rs763284415; called by mutect2, pindel
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 32/153 reads (21%) | catalogued as rs749150409; called by mutect2, varscan2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 40/284 reads (14%) | catalogued as rs760021495; called by mutect2, varscan2
- KCNB2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750665772, COSV73051163; called by muse, mutect2, varscan2
- KCNJ15 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772620107, COSV60810335; called by muse, mutect2, varscan2
- KRT16 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs370377321; called by muse, mutect2, varscan2
- LCE2C | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs199924989, COSV64228505; called by muse, mutect2, varscan2
- LCMT1 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs995675568, COSV66725785; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 44/223 reads (20%) | catalogued as rs746133895; called by mutect2, varscan2
- MAP7D3 | c.922dup p.Q308Pfs*25 | Frame Shift Ins (INS) | VAF 20/163 reads (12%) | catalogued as rs746202015; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 26/140 reads (19%) | catalogued as rs777328830; called by mutect2, varscan2
- MCM7 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751951140, COSV57995022; called by muse, mutect2, varscan2
- MYO1B | c.2767T>C p.C923R (on ENST00000304164; = p.C865R on NM_012223.5) | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58433490; called by muse, mutect2, varscan2
- NLRP3 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 207/832 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as rs765925466, COSV60219292, COSV60225201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP210L | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 36/156 reads (23%) | catalogued as rs771522844, COSV55141015; called by muse, varscan2
- OR10W1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- OR2H1 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759165826, COSV65810709; called by muse, mutect2, varscan2
- OR4D5 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 407/957 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs142766960, COSV58305795; called by muse, mutect2, varscan2
- OR8K3 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57131412; called by muse, mutect2, varscan2
- PCDHGC3 | c.2050dup p.R684Pfs*41 | Frame Shift Ins (INS) | VAF 14/141 reads (10%) | catalogued as rs764598056; called by mutect2, pindel
- PGM5 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs182577861; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 27/193 reads (14%) | catalogued as rs749506841; called by mutect2, varscan2
- PLEKHG7 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs115752910, COSV60821400; called by muse, mutect2, varscan2
- PON1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 35/530 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs987766326, COSV55931497; called by muse, mutect2
- PPEF2 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs763143738, COSV54423837; called by muse, mutect2, varscan2
- QSER1 | c.2431A>G p.T811A (on ENST00000399302; = p.T940A on NM_001076786.3) | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs751733643; called by muse, mutect2, varscan2
- RIPK1 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as rs370418004; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 30/130 reads (23%) | catalogued as rs759765382; called by mutect2, varscan2
- SALL2 | c.1586dup p.G530Rfs*3 | Frame Shift Ins (INS) | VAF 28/218 reads (13%) | catalogued as rs755171367; called by mutect2, varscan2
- TAF1B | c.306C>T p.N102= | Splice Region (SNP) | VAF 28/116 reads (24%) | catalogued as rs376441869; called by muse, mutect2, varscan2
- TAF1L | c.3754C>T p.R1252W | Missense Mutation (SNP) | VAF 636/976 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54259076; called by muse, mutect2, varscan2
- UMODL1 | c.1227C>A p.H409Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs754877661, COSV61160815; called by muse, mutect2, varscan2
- AC126283.2 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 23/637 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCAS1 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 36/671 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- BIVM-ERCC5 | c.854dup p.Y285* | Nonsense Mutation (INS) | VAF 106/418 reads (25%) | called by mutect2, pindel, varscan2
- DCLK3 | c.1895G>A p.S632N | Missense Mutation (SNP) | VAF 39/669 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- JADE3 | c.721A>G p.S241G | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LNX1 | c.383G>A p.C128Y (on ENST00000263925 / NM_001126328.3; = p.C32Y on NM_032622.2) | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2
- MMP20 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 30/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- MUC16 | c.17020G>T p.V5674L | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); called by muse, mutect2
- PCDHA6 | c.347T>A p.V116D | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCYT1A | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 146/933 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.099); called by muse, varscan2
- PHACTR2 | c.1035G>C p.Q345H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- PLEKHA4 | c.1843dup p.R615Pfs*17 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by pindel, varscan2
- PTEN | c.889del p.D297Ifs*10 | Frame Shift Del (DEL) | VAF 197/691 reads (29%) | called by mutect2, pindel, varscan2
- SLC20A1 | c.611G>T p.C204F | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- SOGA3 | c.1748G>A p.R583K | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- STAG2 | c.2407_2408del p.M803Vfs*5 | Frame Shift Del (DEL) | VAF 68/163 reads (42%) | called by mutect2, pindel, varscan2
- ZNF197 | c.905A>G p.E302G | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by mutect2, varscan2
- ARHGEF10L | c.2892C>T p.P964= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs749642671, COSV51435443, COSV99392841; called by muse, mutect2, varscan2
- ASZ1 | c.1005A>G p.V335= | Silent (SNP) | VAF 52/414 reads (13%) | catalogued as rs773571018, COSV52914252; called by muse, mutect2, varscan2
- BRWD3 | c.5080C>A p.R1694= | Silent (SNP) | VAF 10/191 reads (5%) | called by muse, mutect2
- CASR | c.648C>T p.D216= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs774470582, COSV56134230; ClinVar: likely benign; called by muse, mutect2, varscan2
- CEP112 | c.2181G>A p.E727= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV67141781; called by muse, mutect2, varscan2
- F2R | c.861G>A p.T287= | Silent (SNP) | VAF 67/611 reads (11%) | catalogued as rs780737633, COSV59928363; called by muse, varscan2
- GABBR1 | c.234C>T p.V78= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1562129796, COSV63543266; called by muse, mutect2, varscan2
- KIF2B | c.555C>T p.Y185= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs369155067, COSV52132496; called by muse, mutect2, varscan2
- LRIG3 | c.1896C>A p.P632= | Silent (SNP) | VAF 82/216 reads (38%) | catalogued as COSV57866269; called by muse, varscan2
- PPP6C | c.300G>A p.K100= | Silent (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- PRELP | c.921C>T p.P307= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as rs370818372; called by muse, mutect2
- RBM47 | c.552C>T p.Y184= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs779152879, COSV55936286; called by muse, mutect2, varscan2
- RNF133 | c.837C>T p.H279= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV100411507; called by muse, mutect2
- STAB2 | c.342T>G p.G114= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV66341749; called by mutect2, varscan2
- STAMBP | c.30G>A p.P10= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs750254653; called by muse, mutect2
- STMN4 | c.540C>T p.N180= (on ENST00000265770 / NM_001283054.2; = p.N207= on NM_030795.4) | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
